Gene-level copy-number profile of tumor specimen TCGA-AO-A0JE-01A from TCGA case TCGA-AO-A0JE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.4 years (19,516 days).
Specimen TCGA-AO-A0JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.3110bb7f-d80d-4f08-9758-d90368f07cf0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A0JE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f16a115d-00d6-401b-8d62-1ec689a740b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,704; copy number 2: 36,048; copy number 3: 6,998; copy number 4: 2,030; copy number 5: 470; copy number 6: 683; copy number 7: 397; copy number 8: 197; copy number 9: 48; copy number 10: 115; copy number 11: 125.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A0JE-01A-11D-A059-01): tumor purity 0.48, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,035 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–4,147,429, 95 genes, copy number 5 (broad region; genes not listed).
- chr7:71,779,491–72,447,151, 1 gene, copy number 6 (within-gene range 3–6): CALN1.
- chr7:72,103,181–73,988,767, 62 genes, copy number 6 (broad region; genes not listed).
- chr7:74,289,407–75,738,962, 45 genes, copy number 6 (within-gene range 2–6): CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP, GTF2IRD2B, NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1, POM121C, AC211429.1, SPDYE5, PMS2P3, Y_RNA, HIP1, AC004491.1.
- chr8:60,678,740–61,501,645, 11 genes, copy number 5 (within-gene range 1–5): CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1.
- chr8:108,131,100–108,787,594, 9 genes, copy number 9 (within-gene range 2–9): AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:114,282,067–116,325,062, 8 genes, copy number 8–11: AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1.
- chr8:116,642,130–117,540,262, 15 genes, copy number 9: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16.
- chr8:120,535,745–123,290,503, 40 genes, copy number 6–8 (within-gene range 6–13): SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1.
- chr8:124,141,888–133,963,259, 145 genes, copy number 5–11 (broad region; genes not listed).
- chr8:135,859,369–138,914,041, 12 genes, copy number 5–8: LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1.
- chr8:140,940,562–143,384,221, 75 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–7,713,340, 409 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:6,573,767–29,370,272, 575 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr16:49,847,018–51,525,157, 53 genes, copy number 5 (within-gene range 2–5): AC027348.1, AC007603.2, AC007603.1, RPL34P29, AC007603.3, CNEP1R1, AC007610.1, AC007610.3, Metazoa_SRP, ACTG1P16, HEATR3, AC007610.4, RNY4P3, AC007610.2, AC007610.5, RPL10P14, SNORA70, TENT4B, ADCY7, MIR6771, BRD7, AC007493.2, LINC02178, AC007493.1, NKD1, AC007608.2, AC007608.4, AC007608.1, AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1.
- chr17:28,319,200–31,095,450, 176 genes, copy number 5–11 (broad region; genes not listed).
- chr17:31,133,182–31,138,518, 1 gene, copy number 5: AC079915.1.
- chr17:38,936,432–39,864,312, 35 genes, copy number 7 (within-gene range 1–7): FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr19:57,664,280–58,605,223, 88 genes, copy number 6 (broad region; genes not listed).
- chr20:8,077,251–8,968,360, 1 gene, copy number 6 (within-gene range 3–6): PLCB1.
- chr20:8,248,704–9,481,242, 6 genes, copy number 6: PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4.
- chr20:13,995,369–16,053,197, 1 gene, copy number 5 (within-gene range 4–5): MACROD2.
- chr20:14,127,400–21,514,064, 131 genes, copy number 5–7 (broad region; genes not listed).
- chr20:25,368,275–26,251,546, 29 genes, copy number 5 (within-gene range 3–5): PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr20:61,252,261–61,940,617, 1 gene, copy number 5 (within-gene range 3–5): CDH4.
- chr20:61,369,879–62,143,440, 11 genes, copy number 5: BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7.

Autosomal genes at a single copy (total copy number 1): 11,866. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
